Somatic mutation profile of tumor specimen TCGA-56-7822-01A (aliquot TCGA-56-7822-01A-11D-2122-08) from TCGA case TCGA-56-7822, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 76.0 years (27,755 days).
Specimen TCGA-56-7822-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bada4c2-0d42-410c-96c3-6de22264eead.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-7822-10A (Blood Derived Normal), aliquot TCGA-56-7822-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cecc06c-68e1-4c08-a320-fe0ee0627093

The open-access MAF lists 393 somatic variants for this specimen: 291 protein-altering or splice-affecting, 97 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 255, Silent 97, Nonsense Mutation 24, Splice Site 6, Frame Shift Del 5, Intron 4, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.470T>A p.V157D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131691023, CM138009, CM161671, COSV52675572, COSV52699845, COSV52722122; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.897G>T p.M299I (on ENST00000297504 / NM_001282291.2; = p.M282I on NM_007188.5) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99873468; called by muse, mutect2, varscan2
- ACVRL1 | c.1314G>C p.M438I | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV101187757, COSV66361049; called by muse, mutect2
- ADAMTS16 | c.2427C>A p.Y809* | Nonsense Mutation (SNP) | VAF 30/164 reads (18%) | catalogued as COSV57000736; called by muse, mutect2, varscan2
- ADGRE1 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99164979; called by muse, mutect2, varscan2
- AFDN | c.3855C>G p.Y1285* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100652262; called by muse, mutect2, varscan2
- AFF2 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV100648691; called by muse, mutect2, varscan2
- AFG1L | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.102); catalogued as COSV100933815; called by muse, mutect2, varscan2
- AGAP1 | c.1737G>A p.W579* (on ENST00000304032 / NM_001037131.3; = p.W526* on NM_014914.5) | Nonsense Mutation (SNP) | VAF 79/147 reads (54%) | catalogued as COSV100363346; called by muse, mutect2, varscan2
- ALB | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99890439; called by muse, mutect2, varscan2
- ALK | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV66558092, COSV66562199; called by muse, mutect2, varscan2
- ANAPC5 | c.2173G>T p.G725W | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99029017; called by muse, varscan2
- ANK3 | c.13039G>C p.E4347Q (on ENST00000280772 / NM_001320874.2; = p.E971Q on NM_001149.3) | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.382); catalogued as COSV99777630; called by muse, mutect2, varscan2
- ANKRD11 | c.4330G>A p.E1444K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV56375975, COSV99967915; called by muse, mutect2, varscan2
- ARHGDIB | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV99075493, COSV99844127; called by muse, mutect2, varscan2
- ARMCX2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.438); catalogued as COSV100167978; called by muse, mutect2, varscan2
- ASIC4 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs1240502010, COSV100761521; called by muse, mutect2, varscan2
- ATP11A | c.2244-2A>G p.X748_splice | Splice Site (SNP) | VAF 54/125 reads (43%) | catalogued as COSV99367100; called by muse, mutect2, varscan2
- ATP2B3 | c.2632C>A p.P878T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99682619; called by muse, mutect2, varscan2
- ATP6V1C1 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as COSV101214778; called by muse, mutect2, varscan2
- ATXN3L | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as COSV101019257; called by muse, mutect2, varscan2
- AVPR2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100509372; called by muse, mutect2, varscan2
- BAZ2B | c.2896G>C p.E966Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as rs901808902, COSV99680828; called by muse, mutect2, varscan2
- BCOR | c.4966G>A p.V1656M (on ENST00000378444 / NM_001123385.2; = p.V1622M on NM_017745.6) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100652690; called by muse, mutect2
- BDKRB1 | c.519C>A p.F173L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV99387680; called by muse, mutect2, varscan2
- BEST3 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99876016; called by muse, mutect2
- BOC | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.195); catalogued as rs373840149, COSV99847790; called by muse, mutect2, varscan2
- BTN3A1 | c.843C>G p.F281L | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV99175616; called by muse, mutect2, varscan2
- C22orf23 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV50778215, COSV99316915; called by muse, mutect2, varscan2
- CAMTA2 | c.2230G>C p.E744Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100772275; called by muse, mutect2, varscan2
- CAPRIN1 | c.1-1G>A p.X1_splice | Splice Site (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100403416; called by muse, mutect2
- CCER1 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs780834488, COSV100726901; called by muse, mutect2, varscan2
- CD101 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99868928; called by muse, mutect2, varscan2
- CD163L1 | c.4339C>T p.P1447S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.447); catalogued as COSV58013995; called by muse, mutect2, varscan2
- CD226 | c.545T>G p.V182G | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV99710635; called by muse, mutect2, varscan2
- CD300C | c.570G>T p.L190F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100423139; called by muse, mutect2, varscan2
- CDH23 | c.6454G>T p.V2152F | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as COSV56480716, COSV99818156; called by muse, mutect2, varscan2
- CDH5 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.098); catalogued as COSV100438901; called by muse, mutect2, varscan2
- CELF6 | c.1187G>A p.C396Y | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99763496; called by muse, mutect2, varscan2
- CEP164 | c.1725-1G>T p.X575_splice | Splice Site (SNP) | VAF 21/121 reads (17%) | catalogued as COSV99632302; called by muse, mutect2, varscan2
- CFAP100 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs377186686, COSV100729015; called by muse, mutect2
- CFAP47 | c.5000C>A p.S1667Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as COSV100544747, COSV57973783; called by muse, mutect2, varscan2
- CFAP65 | c.5163G>C p.Q1721H | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100444381; called by muse, mutect2, varscan2
- CHD4 | c.3537G>C p.M1179I (on ENST00000357008 / NM_001363606.2; = p.M1192I on NM_001273.5) | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100537119; called by muse, mutect2, varscan2
- CHKB | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100376429; called by muse, mutect2, varscan2
- CLEC4E | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572354909, COSV55225647; called by muse, mutect2, varscan2
- CNKSR2 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV99666991; called by muse, mutect2, varscan2
- COBL | c.2759C>T p.S920L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV99470848; called by muse, mutect2, varscan2
- COL25A1 | c.1711-1G>T p.X571_splice | Splice Site (SNP) | VAF 3/26 reads (12%) | catalogued as COSV101210993; called by muse, mutect2
- COL4A3 | c.1340C>A p.P447Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV101169734; called by muse, mutect2, varscan2
- COL6A1 | c.1078C>G p.P360A | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); catalogued as COSV100719813; called by muse, mutect2
- CPA5 | c.1029G>C p.Q343H | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs782609284, COSV100812206; called by muse, mutect2, varscan2
- CPS1 | c.4072C>T p.P1358S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99241384; called by muse, mutect2, varscan2
- CR1 | c.4625C>T p.T1542M | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.817); catalogued as rs376660723; called by muse, mutect2, varscan2
- CR1L | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54331616, COSV99686661; called by muse, mutect2, varscan2
- CRACD | c.2306T>C p.L769P | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99948309; called by muse, mutect2, varscan2
- CSMD3 | c.3349C>T p.H1117Y (on ENST00000297405 / NM_001363185.1; = p.H1013Y on NM_052900.3) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.552); catalogued as COSV99820500, COSV99843814; called by muse, mutect2, varscan2
- CTCFL | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99711921; called by muse, mutect2, varscan2
- DCBLD2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100471177; called by muse, mutect2, varscan2
- DCT | c.240G>C p.Q80H | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV100986075; called by muse, mutect2, varscan2
- DDHD1 | c.772G>T p.V258F (on ENST00000323669; = p.V455F on NM_030637.3) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100078856; called by muse, mutect2, varscan2
- DDX42 | c.2753A>G p.K918R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.055); catalogued as COSV100834799; called by muse, mutect2, varscan2
- DENND2C | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101283873; called by muse, mutect2, varscan2
- DES | c.1398G>T p.Q466H | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as CX151279, COSV100900280; called by muse, mutect2, varscan2
- DHX33 | c.988T>G p.S330A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as COSV99834178; called by muse, mutect2, varscan2
- DHX36 | c.2302G>C p.E768Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV100273179; called by muse, mutect2, varscan2
- DHX37 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100438876, COSV58139618; called by muse, mutect2, varscan2
- DLGAP4 | c.2262G>C p.K754N (on ENST00000339266 / NM_001365621.1; = p.K751N on NM_014902.6) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.503); catalogued as COSV100210652; called by muse, mutect2, varscan2
- DNAAF2 | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100023694; called by muse, mutect2, varscan2
- DNAH11 | c.1359G>T p.W453C | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100176119; called by muse, mutect2, varscan2
- DNAH5 | c.7194G>T p.M2398I | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as COSV99443251; called by muse, mutect2, varscan2
- DNAH8 | c.4258A>C p.N1420H | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV100542622; called by muse, mutect2, varscan2
- DSCAM | c.5361C>A p.S1787R | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101258665; called by muse, mutect2, varscan2
- DTX3L | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV99949795; called by muse, mutect2, varscan2
- DUSP12 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.24); catalogued as COSV100909652; called by muse, mutect2
- DYSF | c.2422C>T p.R808W | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345130790, COSV50490274; called by muse, mutect2, varscan2
- EMILIN3 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100182236, COSV60035194; called by muse, mutect2, varscan2
- ERV3-1 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV99275058; called by muse, mutect2, varscan2
- ESPL1 | c.3249G>T p.K1083N | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV99228661; called by muse, mutect2, varscan2
- FAM120C | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.442); catalogued as COSV100069438, COSV60257268; called by muse, mutect2
- FAM184A | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100137242; called by muse, mutect2, varscan2
- FAM47B | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100263899; called by muse, mutect2, varscan2
- FAM47C | c.2057G>T p.R686L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.722); catalogued as COSV100792224, COSV63724689; called by muse, mutect2, varscan2
- FAM50A | c.780C>A p.H260Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV99340791; called by muse, mutect2, varscan2
- FANCM | c.2920G>C p.D974H | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV99950236; called by muse, mutect2, varscan2
- FMO3 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.087); catalogued as COSV100882386; called by muse, mutect2, varscan2
- FNIP1 | c.96G>T p.W32C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100330163; called by muse, mutect2, varscan2
- FOLH1 | c.1491G>T p.W497C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99922502; called by muse, mutect2, varscan2
- FOLH1 | c.1490G>T p.W497L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs934589148, COSV99922505; called by muse, mutect2, varscan2
- FOXA2 | c.471C>G p.H157Q (on ENST00000377115 / NM_153675.3; = p.H163Q on NM_021784.5) | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs144279222, COSV101008188; called by muse, mutect2, varscan2
- GGTLC1 | c.571C>G p.Q191E | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99600311; called by muse, mutect2, varscan2
- GLYATL1 | c.500C>T p.P167L (on ENST00000317391 / NM_001354699.1; = p.P198L on NM_080661.4) | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100265061; called by muse, mutect2, varscan2
- GNB4 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99223958; called by muse, mutect2, varscan2
- GNPTAB | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV100171507; called by muse, mutect2
- GORAB | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV100883748; called by mutect2, varscan2
- GPR149 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV101078005; called by muse, mutect2, varscan2
- GPRASP1 | c.3748G>C p.D1250H | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100850878; called by muse, mutect2, varscan2
- GPRASP2 | c.1869G>T p.M623I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV100176473; called by muse, mutect2, varscan2
- GRHPR | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs764111479, COSV58944536; called by muse, mutect2, varscan2
- GRIA2 | c.1710C>A p.Y570* | Nonsense Mutation (SNP) | VAF 33/105 reads (31%) | catalogued as COSV52380934, COSV99642409; called by muse, mutect2, varscan2
- GRM5 | c.2497G>C p.V833L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100549600, COSV59624917; called by muse, mutect2, varscan2
- GSDME | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs369233573; called by muse, mutect2, varscan2
- GUCY1A1 | c.1943G>A p.S648N | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV99636846; called by muse, mutect2, varscan2
- H2AC4 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52517894; called by muse, mutect2
- H2BC10 | c.48G>C p.K16N | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.771); catalogued as rs768250254, COSV59952909; called by muse, mutect2, varscan2
- H3-4 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as COSV100797341, COSV64211202; called by muse, mutect2, varscan2
- HHAT | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.685); catalogued as rs113371678, COSV99801954; called by muse, mutect2, varscan2
- HSF2 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as COSV100869621; called by muse, mutect2, varscan2
- HSPA12B | c.566G>C p.R189T | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99653756; called by muse, varscan2
- HSPA13 | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1462835658, COSV99579775; called by muse, mutect2, varscan2
- HTR7 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV53292144, COSV99518591; called by muse, mutect2, varscan2
- HTT | c.7652G>C p.R2551T | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100750239; called by muse, mutect2, varscan2
- IGF2R | c.2891T>A p.I964N | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV100806654; called by muse, mutect2, varscan2
- IGKV3-15 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs752065906; called by muse, mutect2, varscan2
- INHBA | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 126/494 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.022); catalogued as COSV99636946; called by muse, mutect2, varscan2
- IPO5 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV99846878; called by muse, mutect2
- ITFG2 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV99957929; called by muse, mutect2, varscan2
- ITPR2 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV101189750, COSV67274739; called by muse, mutect2, varscan2
- JAK2 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as COSV101070065; called by muse, mutect2, varscan2
- JAKMIP1 | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 48/134 reads (36%) | catalogued as COSV99288297; called by muse, mutect2, varscan2
- KAT6A | c.2872C>G p.L958V | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.068); catalogued as COSV99704154; called by muse, mutect2, varscan2
- KCNA3 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV63902106; called by muse, mutect2, varscan2
- KCNA4 | c.1607G>C p.G536A | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.336); catalogued as rs1170149460, COSV100068387, COSV60255007; called by muse, mutect2, varscan2
- KDM2B | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV65640102; called by muse, mutect2, varscan2
- KDM5A | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV101238534; called by muse, mutect2
- KIF5A | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99672286; called by muse, mutect2, varscan2
- KLRG1 | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV99867993; called by muse, mutect2, varscan2
- KNL1 | c.5311G>C p.E1771Q (on ENST00000346991 / NM_170589.5; = p.E1745Q on NM_144508.5) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV100705734, COSV100706617; called by muse, mutect2, varscan2
- LLGL1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.185); catalogued as rs747567402; called by muse, mutect2, varscan2
- LMNTD2 | c.363C>G p.I121M | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV99529267; called by muse, mutect2
- LRP2 | c.3226C>T p.H1076Y | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV99785797, COSV99787993; called by muse, mutect2, varscan2
- LTBP2 | c.4572G>T p.K1524N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as COSV99999401, COSV99999599; called by muse, mutect2, varscan2
- LY6H | c.413C>G p.A138G | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV100713829; called by mutect2, varscan2
- MAGEA8 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.298); catalogued as COSV99674316; called by muse, mutect2, varscan2
- MAGEC1 | c.1457C>A p.S486Y | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.608); catalogued as COSV99594590; called by muse, mutect2, varscan2
- MAML1 | c.2207G>A p.G736D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV99482806; called by muse, mutect2
- MASTL | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100668779; called by muse, mutect2, varscan2
- MBTPS1 | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100597248; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MED12 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100375292, COSV61334729; called by muse, mutect2, varscan2
- MEIOC | c.1165C>G p.Q389E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.717); catalogued as rs1367222644, COSV100740119; called by muse, mutect2, varscan2
- MFGE8 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV99183926; called by muse, mutect2, varscan2
- MGAM | c.2876G>T p.R959M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV101527330; called by muse, mutect2, varscan2
- MMP21 | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 30/141 reads (21%) | catalogued as rs752375826, COSV100916656; called by muse, mutect2, varscan2
- MMRN1 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 25/110 reads (23%) | catalogued as rs1253588422, COSV99306234; called by muse, mutect2, varscan2
- MORC4 | c.1822G>T p.G608W | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99716669; called by muse, mutect2, varscan2
- MOS | c.624G>C p.L208F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.327); catalogued as rs753368455, COSV100322667; called by muse, mutect2, varscan2
- MPEG1 | c.1449C>G p.F483L | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV57094517, COSV99914848; called by muse, mutect2, varscan2
- MPP1 | c.568G>T p.D190Y | Missense Mutation (SNP) | VAF 134/567 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101053589; called by muse, mutect2, varscan2
- MRAP2 | c.246G>C p.E82D | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.543); catalogued as COSV100004556, COSV57634882; called by muse, mutect2, varscan2
- MTMR12 | c.2147C>G p.S716C | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.188); catalogued as COSV99373276; called by muse, mutect2, varscan2
- MTOR | c.7217T>C p.V2406A | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV63873383, COSV63874327; called by muse, mutect2, varscan2
- MTOR | c.4171C>T p.R1391* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as rs1296711816, COSV100815589, COSV63874955; called by muse, mutect2, varscan2
- MTR | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855659, COSV100855808; called by muse, mutect2, varscan2
- MTSS1 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.566); catalogued as rs533015192, COSV100274225, COSV61499020; called by muse, mutect2, varscan2
- MUC6 | c.3716C>A p.S1239* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV101424316; called by muse, mutect2, varscan2
- NALCN | c.4586C>A p.T1529N | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99212644; called by muse, mutect2, varscan2
- NIN | c.3492G>T p.Q1164H | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV55407925, COSV99810994; called by muse, mutect2, varscan2
- NLRP12 | c.1587C>G p.D529E | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781712648, COSV60743835, COSV60758270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP12 | c.1279A>T p.T427S | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV100144659; called by muse, mutect2, varscan2
- NLRP12 | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100144665; called by muse, mutect2, varscan2
- NLRP4 | c.1422C>A p.H474Q | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as COSV100015349, COSV56711766; called by muse, mutect2, varscan2
- NLRP9 | c.1382G>C p.R461P | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as rs758078069, COSV100242391, COSV100242973; called by muse, mutect2
- NPAP1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.101); catalogued as rs759520625, COSV100274550; called by muse, varscan2
- NR3C1 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51544609; called by muse, mutect2, varscan2
- NUP153 | c.4370C>G p.S1457C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV99467152; called by muse, mutect2, varscan2
- OR2M5 | c.161A>T p.Q54L | Missense Mutation (SNP) | VAF 113/400 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); catalogued as COSV100822699; called by muse, mutect2, varscan2
- OR2T12 | c.937C>G p.Q313E | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV100527465; called by muse, mutect2, varscan2
- OR4D5 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100189634; called by muse, mutect2, varscan2
- OR52A1 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV100200376; called by muse, mutect2, varscan2
- OR56B4 | c.452C>A p.T151K | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV100337612; called by muse, mutect2, varscan2
- OR5B17 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.044); catalogued as COSV100641834; called by muse, mutect2
- OR5P2 | c.915A>G p.I305M | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.043); catalogued as COSV61489883; called by muse, mutect2, varscan2
- PAPPA | c.443C>G p.S148* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100072545, COSV60287541; called by muse, mutect2, varscan2
- PASD1 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100948982, COSV64854842; called by muse, mutect2, varscan2
- PCDH11Y | c.506C>A p.P169Q (on ENST00000400457 / NM_032973.2; = p.P158Q on NM_032971.3) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99290206; called by mutect2, varscan2
- PCDH8 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV100131071; called by muse, varscan2
- PCDH9 | c.2249G>T p.R750L | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100117321, COSV60531469; called by muse, mutect2, varscan2
- PCGF1 | c.507G>C p.L169F | Missense Mutation (SNP) | VAF 95/371 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV52042615, COSV99283132, COSV99283455; called by muse, mutect2, varscan2
- PCNT | c.7141G>A p.A2381T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs750546295, COSV100854928; called by muse, mutect2, varscan2
- PELP1 | c.2347G>A p.D783N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99342340; called by muse, mutect2, varscan2
- PHACTR3 | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100732133; called by muse, mutect2, varscan2
- PHF8 | c.1565C>T p.S522F (on ENST00000357988 / NM_001184896.1; = p.S486F on NM_015107.3) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV100153686; called by muse, mutect2, varscan2
- PIK3CB | c.1915C>A p.L639I | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56683978, COSV56691831; called by muse, mutect2, varscan2
- PLA2G7 | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.586); catalogued as COSV99221033; called by muse, mutect2, varscan2
- PLEC | c.3581C>T p.S1194L (on ENST00000322810 / NM_201380.4; = p.S1084L on NM_000445.5) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs782710264, COSV59688582; called by muse, mutect2
- PLXNB3 | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs141796383, COSV62802459; called by muse, mutect2, varscan2
- POMK | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV100505623; called by muse, mutect2, varscan2
- POMZP3 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); catalogued as COSV99300251; called by muse, mutect2, varscan2
- POPDC2 | c.188G>T p.C63F | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99950783; called by muse, mutect2, varscan2
- POU3F4 | c.379A>C p.S127R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV100937140, COSV64541357; called by muse, mutect2, varscan2
- PPM1E | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV100375575; called by muse, mutect2, varscan2
- PPM1E | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV100375576; called by muse, mutect2, varscan2
- PRDM2 | c.231+1G>C p.X77_splice | Splice Site (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99340512; called by muse, mutect2, varscan2
- PRDX4 | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101026669; called by muse, mutect2, varscan2
- PRKG2 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as rs199612321, COSV52334969; called by muse, mutect2, varscan2
- PRMT2 | c.1117A>T p.T373S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as COSV99388383; called by muse, mutect2
- PRRC2A | c.5329G>A p.D1777N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV99276192; called by muse, mutect2, varscan2
- PSAPL1 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100040232; called by muse, mutect2, varscan2
- PSMD10 | c.46A>G p.S16G | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99480574; called by muse, mutect2, varscan2
- PTBP3 | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.924); catalogued as COSV100533911; called by muse, mutect2, varscan2
- PTPRD | c.497T>A p.V166E | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100642421; called by muse, mutect2, varscan2
- QTRT2 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.199); catalogued as COSV99846785; called by muse, mutect2, varscan2
- RB1CC1 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99204945; called by muse, mutect2, varscan2
- RBL1 | c.2707G>C p.E903Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV100726828; called by muse, mutect2
- RGS21 | c.355A>T p.M119L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs1478968728, COSV101313966; called by muse, mutect2, varscan2
- RGS22 | c.1826C>G p.S609* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100692922, COSV62665595; called by muse, mutect2, varscan2
- RHEX | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs782267753, COSV58980322; called by muse, mutect2
- RIMS1 | c.1747C>A p.H583N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99322842; called by muse, mutect2, varscan2
- RIMS2 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101343929; called by muse, varscan2
- ROBO4 | c.1402C>A p.P468T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100127178, COSV100127700; called by muse, mutect2, varscan2
- SAMD9 | c.3130G>C p.E1044Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as COSV101180102; called by muse, mutect2, varscan2
- SCN1B | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV52893805, COSV99386426; called by muse, mutect2
- SGCG | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1241846735, COSV99522477; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3BP5L | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 24/144 reads (17%) | catalogued as COSV100821937, COSV63539765; called by muse, mutect2, varscan2
- SHOC1 | c.2123T>C p.I708T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs780884055, COSV100597138; called by muse, mutect2, varscan2
- SHPRH | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.091); catalogued as COSV99260984, COSV99261427; called by muse, mutect2
- SIM1 | c.1771C>A p.Q591K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs1415067459, COSV99491739; called by muse, mutect2, varscan2
- SIRT6 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100511100; called by muse, mutect2, varscan2
- SLC16A9 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs752716124, COSV68100588; called by muse, mutect2, varscan2
- SLC18A3 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100339484; called by muse, mutect2, varscan2
- SLC27A6 | c.441C>G p.C147W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321933; called by muse, mutect2, varscan2
- SLC51A | c.557A>C p.Q186P | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99579970; called by muse, mutect2, varscan2
- SLC5A5 | c.1561G>C p.D521H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99714597; called by muse, varscan2
- SLC9C1 | c.3309G>C p.R1103S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99997077, COSV99997745; called by muse, mutect2, varscan2
- SMC1B | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV100662869, COSV62529983; called by muse, mutect2, varscan2
- SMG1 | c.9148G>T p.E3050* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101244877, COSV67175222; called by muse, mutect2, varscan2
- SNTG1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs768385931, COSV52423255; called by muse, mutect2, varscan2
- SNTG1 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs747482110, COSV52447113, COSV52473992; called by muse, mutect2, varscan2
- SP100 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99891860; called by muse, mutect2, varscan2
- SPG11 | c.585G>T p.L195F | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99967794; called by muse, mutect2, varscan2
- SRPK3 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99472849; called by muse, mutect2, varscan2
- SSH2 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99281235; called by muse, mutect2, varscan2
- ST3GAL6 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as rs761826510, COSV54583224; called by muse, mutect2, varscan2
- SYNE1 | c.18980G>A p.S6327N (on ENST00000367255 / NM_182961.4; = p.S6256N on NM_033071.3) | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.858); catalogued as COSV99549551; called by muse, mutect2
- SYNE1 | c.17037G>A p.M5679I (on ENST00000367255 / NM_182961.4; = p.M5608I on NM_033071.3) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.16); catalogued as COSV99549552; called by muse, mutect2, varscan2
- SYNE1 | c.3616G>C p.E1206Q (on ENST00000367255 / NM_182961.4; = p.E1213Q on NM_033071.3) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.424); catalogued as COSV99549557; called by muse, mutect2, varscan2
- TAF1 | c.1405C>G p.Q469E (on ENST00000373790 / NM_138923.4; = p.Q490E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99334079; called by muse, mutect2, varscan2
- TCEAL3 | c.322C>G p.R108G | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99685179; called by muse, mutect2, varscan2
- TEX44 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100009539, COSV58355557; called by muse, mutect2, varscan2
- TLR3 | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 54/259 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as rs1401745340, COSV99710724; called by muse, mutect2, varscan2
- TMLHE | c.521A>T p.N174I | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV100544520; called by muse, mutect2, varscan2
- TOGARAM1 | c.2279C>T p.T760I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs757252205, COSV100817692; called by muse, mutect2, varscan2
- TOP1MT | c.780C>G p.I260M | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.671); catalogued as COSV100239079; called by muse, mutect2, varscan2
- TP63 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.626); catalogued as COSV53201970, COSV99284940; called by muse, mutect2, varscan2
- TRHDE | c.2153C>A p.A718E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV53856884, COSV99668440; called by muse, mutect2, varscan2
- TRIM51 | c.868A>T p.T290S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.02); catalogued as rs1383180629, COSV99791966; called by muse, mutect2
- TRPC5 | c.2509T>C p.F837L | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.827); catalogued as COSV99458910; called by muse, mutect2, varscan2
- TSC22D1 | c.1713G>C p.M571I | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV101488051; called by muse, mutect2, varscan2
- TSPYL2 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV100966253; called by muse, mutect2, varscan2
- TTN | c.14652G>A p.W4884* (on ENST00000591111; = p.W3957* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/119 reads (23%) | catalogued as COSV100588743; called by muse, mutect2, varscan2
- TUBA1C | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as COSV99988592; called by muse, mutect2, varscan2
- U2SURP | c.1272A>C p.E424D | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.194); catalogued as COSV101204291; called by muse, mutect2, varscan2
- UBE3A | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99216570; called by muse, mutect2
- UGT1A6 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100529219, COSV59390940; called by muse, mutect2, varscan2
- UGT2B11 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV101485204; called by muse, mutect2, varscan2
- UHRF1BP1 | c.982A>T p.I328F | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV51957580; called by muse, varscan2
- ULK1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1330502070, COSV100416406; called by muse, mutect2, varscan2
- UNC79 | c.7677G>A p.M2559I (on ENST00000393151 / NM_001346218.2; = p.M2382I on NM_020818.5) | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV99825134; called by muse, mutect2
- USH2A | c.11621T>C p.V3874A | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56401365; called by muse, mutect2, varscan2
- USP13 | c.2374G>T p.A792S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99830590, COSV99831231; called by muse, mutect2, varscan2
- USP34 | c.6604G>C p.E2202Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV101276489; called by muse, mutect2, varscan2
- VAPA | c.511G>T p.E171* (on ENST00000400000 / NM_194434.3; = p.E216* on NM_003574.6) | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100485986; called by muse, mutect2, varscan2
- VPS13B | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs367561688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs1370204743, COSV100660457; called by muse, mutect2, varscan2
- VPS16 | c.2119G>T p.G707C | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as rs775424332, COSV100988224; called by muse, mutect2, varscan2
- WASHC5 | c.2758A>G p.K920E | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.95); PolyPhen benign (0.092); catalogued as COSV100572376; called by muse, mutect2, varscan2
- WWOX | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101282823; called by muse, mutect2
- ZCCHC12 | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.181); catalogued as COSV100038368; called by muse, mutect2, varscan2
- ZIM2 | c.1556A>T p.E519V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99686636; called by muse, mutect2, varscan2
- ZMAT1 | c.1754G>T p.R585I | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as COSV100858621; called by muse, mutect2, varscan2
- ZNF101 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100543434; called by muse, mutect2, varscan2
- ZNF45 | c.1055G>C p.R352T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99523935; called by mutect2, varscan2
- ZNF462 | c.4240G>C p.E1414Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV99470476, COSV99473498; called by muse, mutect2, varscan2
- ZNF479 | c.121T>A p.Y41N | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100482342; called by muse, mutect2, varscan2
- ZNF527 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs759632113, COSV62230584; called by muse, mutect2, varscan2
- ZNF540 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV100329393; called by muse, mutect2, varscan2
- ZNF639 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | catalogued as COSV100418334; called by muse, mutect2, varscan2
- ZNF646 | c.2038G>A p.G680S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as rs770620794, COSV100336231; called by muse, mutect2, varscan2
- ZNF676 | c.922G>A p.A308T (on ENST00000650058; = p.A276T on NM_001001411.3) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs764278872, COSV68092687; called by muse, mutect2, varscan2
- ZNF7 | c.596A>G p.E199G | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as COSV100295578; called by muse, mutect2, varscan2
- ZNF781 | c.428A>T p.D143V | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV100669083; called by muse, mutect2, varscan2
- ZNF831 | c.2423G>A p.W808* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100925687; called by muse, mutect2, varscan2
- ZNF831 | c.2424G>T p.W808C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1318815159, COSV100925688; called by muse, mutect2, varscan2
- ATP1A4 | c.616_618del p.R206del | In Frame Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- LLGL1 | c.1060+1G>T p.X354_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- MUC6 | c.4085del p.P1362Hfs*94 | Frame Shift Del (DEL) | VAF 29/136 reads (21%) | called by mutect2, pindel, varscan2
- SOCS7 | c.1294del p.L432Cfs*38 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- TKTL1 | c.260del p.S87Cfs*38 | Frame Shift Del (DEL) | VAF 112/411 reads (27%) | called by mutect2, pindel, varscan2
- USP9X | c.391del p.I131Ffs*7 | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | called by mutect2, pindel, varscan2
- ACBD5 | c.147G>C p.V49= (on ENST00000375888 / NM_001352568.1; = p.V51= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV101022431, COSV65521765; called by muse, mutect2, varscan2
- ADGRE2 | c.2340C>T p.L780= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as COSV100215574; called by muse, mutect2, varscan2
- ADGRG4 | c.6906G>A p.E2302= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99794023; called by muse, mutect2, varscan2
- AGAP1 | c.2454C>T p.I818= (on ENST00000304032 / NM_001037131.3; = p.I765= on NM_014914.5) | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs773891428, COSV100363347; called by muse, mutect2, varscan2
- AHNAK | c.2682C>T p.G894= | Silent (SNP) | VAF 160/399 reads (40%) | catalogued as rs1184202733, COSV99945130; called by muse, mutect2, varscan2
- ALG9 | c.1197A>G p.Q399= (on ENST00000614444 / NM_001352418.1; = p.Q406= on NM_024740.2) | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1048321007, COSV101211835; called by muse, mutect2
- ANKRD11 | c.1344G>A p.Q448= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs1453115376, COSV99967924; called by muse, varscan2
- ARAP1 | c.2292G>T p.R764= (on ENST00000393609 / NM_001040118.2; = p.R519= on NM_015242.4) | Silent (SNP) | VAF 23/220 reads (10%) | catalogued as COSV100501392; called by muse, mutect2, varscan2
- ARHGEF12 | c.4506G>A p.Q1502= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV63106287; called by muse, mutect2, varscan2
- ATMIN | c.1098A>G p.L366= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV100214459; called by muse, mutect2
- AXIN2 | c.420G>A p.E140= | Silent (SNP) | VAF 46/168 reads (27%) | catalogued as COSV61059850; called by muse, mutect2, varscan2
- C6orf58 | c.186G>C p.G62= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV100314636, COSV61666400; called by muse, mutect2
- CASS4 | c.2064C>T p.S688= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs917007163, COSV64386312; called by muse, mutect2, varscan2
- CBX8 | c.162C>G p.L54= | Silent (SNP) | VAF 13/168 reads (8%) | catalogued as COSV53936892, COSV99485686; called by muse, mutect2
- CES3 | c.843C>T p.C281= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs767488457, COSV100309759; called by mutect2, varscan2
- CFHR5 | c.27A>T p.L9= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV99887682; called by muse, varscan2
- COL20A1 | c.3513G>A p.G1171= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1171825960, COSV100489731; called by muse, mutect2, varscan2
- CPS1 | c.2919C>T p.D973= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99241381, COSV99243569; called by muse, mutect2
- CPSF2 | c.489C>G p.V163= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV100102392; called by muse, mutect2, varscan2
- DNAJC7 | c.891C>T p.Y297= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV100347385; called by muse, mutect2, varscan2
- DOCK4 | c.2526G>A p.L842= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs767715471, COSV101447731; called by muse, mutect2
- DRAM2 | c.360A>G p.A120= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99713299; called by muse, mutect2, varscan2
- DRP2 | c.276C>T p.N92= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV100871747; called by muse, mutect2, varscan2
- DSG1 | c.108T>C p.N36= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV99935428; called by muse, mutect2, varscan2
- EEPD1 | c.96C>T p.N32= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as COSV99631619; called by muse, mutect2, varscan2
- EFEMP1 | c.30G>C p.L10= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV100816661; called by muse, mutect2, varscan2
- ERGIC2 | c.435T>C p.F145= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV100791919; called by muse, mutect2, varscan2
- FSTL5 | c.1161A>G p.K387= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV100051489; called by mutect2, varscan2
- GMPPA | c.1002G>T p.T334= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as COSV100354421; called by muse, mutect2, varscan2
- GNAT2 | c.466C>T p.L156= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100655778; called by muse, mutect2, varscan2
- GPR52 | c.885T>C p.N295= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV99266728; called by muse, mutect2, varscan2
- GPSM1 | c.1272G>T p.L424= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100696538; called by muse, mutect2
- GRIA2 | c.1345C>T p.L449= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99642407; called by muse, mutect2, varscan2
- GRM8 | c.2112C>A p.S704= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs765177458, COSV100279382, COSV58877631; called by muse, mutect2, varscan2
- ITIH6 | c.3186T>A p.S1062= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV99512667; called by muse, mutect2, varscan2
- KAT6A | c.5667C>A p.R1889= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as COSV99704152; called by muse, mutect2, varscan2
- KCNB1 | c.681C>G p.P227= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100870355; called by muse, mutect2, varscan2
- KCND1 | c.918C>T p.S306= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99501617; called by muse, mutect2, varscan2
- KIAA0513 | c.1080C>T p.F360= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs922835340, COSV99260301; called by muse, varscan2
- L1CAM | c.2763C>A p.P921= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100648814, COSV62827507; called by muse, mutect2, varscan2
- LGALS12 | c.543G>A p.L181= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99736751; called by muse, mutect2, varscan2
- LGI1 | c.246C>T p.I82= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV101004330; called by muse, mutect2, varscan2
- LILRA2 | c.348G>A p.V116= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV99252511; called by muse, mutect2, varscan2
- LIPF | c.39A>T p.V13= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs888468842, COSV99490053; called by muse, mutect2, varscan2
- MADD | c.186G>A p.L62= | Silent (SNP) | VAF 25/259 reads (10%) | catalogued as COSV100210798; called by muse, mutect2, varscan2
- MAGEC1 | c.1458C>A p.S486= | Silent (SNP) | VAF 57/237 reads (24%) | catalogued as COSV53571573; called by muse, mutect2, varscan2
- MAT2A | c.972T>G p.V324= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV99289552; called by muse, mutect2, varscan2
- MC4R | c.891C>T p.I297= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs201921200, COSV100235806; called by muse, mutect2, varscan2
- MSTO1 | c.1248G>A p.V416= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV99824053; called by muse, mutect2, varscan2
- NALCN | c.4587C>T p.T1529= | Silent (SNP) | VAF 76/193 reads (39%) | catalogued as COSV99212643; called by muse, mutect2, varscan2
- NF1 | c.3900C>A p.L1300= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as COSV100645745; called by muse, mutect2
- NHS | c.1476A>G p.R492= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as COSV101196323; called by muse, mutect2, varscan2
- NOS2 | c.1227C>G p.L409= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV100569427; called by muse, mutect2, varscan2
- NRXN3 | c.678C>A p.T226= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs376174039; called by muse, mutect2, varscan2
- NSD1 | c.1035G>A p.P345= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs776701573, COSV100728267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR8G5 | c.375C>A p.A125= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as COSV100422158; called by muse, mutect2
- OTOGL | c.7002T>C p.N2334= (on ENST00000547103; = p.N2325= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100086421; called by muse, mutect2, varscan2
- P3H3 | c.1362G>A p.L454= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV99300724; called by muse, mutect2, varscan2
- PAK1IP1 | c.1101G>C p.L367= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV65435235; called by muse, mutect2, varscan2
- PCDH11Y | c.1914G>T p.T638= (on ENST00000400457 / NM_032973.2; = p.T627= on NM_032971.3) | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99290211; called by muse, mutect2, varscan2
- PHF24 | c.900C>T p.A300= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs374791324; called by muse, mutect2, varscan2
- PHKG2 | c.522C>T p.F174= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100079298; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1245G>T p.R415= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs1204932936, COSV100543985; called by muse, mutect2, varscan2
- POM121L12 | c.786C>A p.S262= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV101374808, COSV68692571; called by muse, mutect2, varscan2
- PRAMEF15 | c.972A>G p.Q324= | Silent (SNP) | VAF 120/341 reads (35%) | called by muse, mutect2, varscan2
- PRR14 | c.379C>T p.L127= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV54913098, COSV99788222; called by muse, mutect2, varscan2
- PSAPL1 | c.1038C>G p.S346= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as COSV100040229, COSV100040448; called by muse, mutect2, varscan2
- PWWP2B | c.952C>T p.L318= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs1564874402, COSV100535560; called by muse, mutect2, varscan2
- RELN | c.7098C>T p.V2366= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100631882; called by muse, mutect2, varscan2
- RGS21 | c.354C>A p.L118= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV101313965; called by muse, mutect2, varscan2
- RNGTT | c.984A>G p.P328= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs139890490, COSV99665238; called by muse, mutect2, varscan2
- RTL9 | c.1959G>T p.L653= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV101511593; called by muse, mutect2, varscan2
- RXFP3 | c.111G>T p.T37= | Silent (SNP) | VAF 50/161 reads (31%) | catalogued as COSV100347146, COSV57504436; called by muse, mutect2, varscan2
- SIGLEC9 | c.174T>C p.H58= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99142364; called by muse, mutect2, varscan2
- SLC10A2 | c.771G>T p.T257= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as rs749337090, COSV99807466; called by muse, mutect2, varscan2
- SLC35A4 | c.51C>T p.A17= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV100021007; called by muse, mutect2, varscan2
- SLC5A11 | c.144G>A p.V48= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV61739739; called by muse, mutect2, varscan2
- SLC5A5 | c.1647G>C p.L549= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV99714598; called by muse, varscan2
- SLCO1B1 | c.1701G>A p.L567= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99917767, COSV99918218; called by muse, varscan2
- SNAP91 | c.2571C>A p.V857= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV52127417, COSV99533985; called by muse, mutect2, varscan2
- SRD5A3 | c.501T>C p.L167= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99947962; called by muse, mutect2, varscan2
- SSTR3 | c.804C>G p.L268= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV100142469; called by muse, mutect2, varscan2
- SSTR4 | c.453T>A p.P151= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV54800273; called by muse, mutect2, varscan2
- ST13 | c.60G>C p.P20= | Silent (SNP) | VAF 30/175 reads (17%) | catalogued as COSV99343893, COSV99344021; called by muse, mutect2, varscan2
- TAF8 | c.756G>A p.E252= | Silent (SNP) | VAF 28/192 reads (15%) | catalogued as COSV100880965, COSV65896029; called by muse, mutect2, varscan2
- TRAF5 | c.900C>T p.G300= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as COSV99807159; called by muse, mutect2, varscan2
- TRGC1 | c.291C>T p.N97= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs756350841; called by muse, mutect2, varscan2
- TRGV8 | c.174G>A p.E58= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs747737346; called by muse, mutect2, varscan2
- TRIM48 | c.447T>C p.A149= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV101338143; called by muse, mutect2, varscan2
- UMODL1 | c.138G>A p.Q46= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV101252854; called by muse, mutect2, varscan2
- VWA3B | c.2103C>A p.S701= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV101345892; called by muse, mutect2, varscan2
- WDR59 | c.123C>T p.I41= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs772038321, COSV100048751; called by muse, mutect2, varscan2
- WNK2 | c.4578A>T p.P1526= (on ENST00000297954 / NM_001282394.1; = p.P1489= on NM_006648.3) | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99940570; called by muse, mutect2, varscan2
- ZNF286A | c.1563C>T p.P521= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101224709; called by muse, mutect2, varscan2
- ZNF419 | c.357G>T p.L119= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99691688; called by muse, mutect2, varscan2
- ZNF518A | c.2058G>A p.V686= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100283271; called by muse, mutect2, varscan2
- ZNF587 | c.540G>A p.L180= | Silent (SNP) | VAF 44/187 reads (24%) | catalogued as COSV100299229; called by muse, mutect2, varscan2
- AFDN | chr6:167826422 C>A | 5'Flank (SNP) | VAF 22/256 reads (9%) | called by muse, mutect2
- MARCHF1 | c.-322-85380C>A | Intron (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- YWHAH | c.87+5580_87+5581insTGT | Intron (INS) | VAF 18/106 reads (17%) | called by muse*, mutect2, varscan2*
- ZNF275 | c.32-760T>A | Intron (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100936096; called by muse, mutect2, varscan2
- ZNF275 | c.32-759G>T | Intron (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100936097; called by muse, mutect2, varscan2
